Somatic mutation profile of tumor specimen TCGA-3G-AB0T-01A (aliquot TCGA-3G-AB0T-01A-11D-A423-09) from TCGA case TCGA-3G-AB0T, project TCGA-THYM (Thymoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Thymoma, type B1, malignant; Tissue or organ of origin: Thymus; Age at diagnosis: 45.8 years (16,728 days).
Specimen TCGA-3G-AB0T-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b889a056-83d2-4a6b-b2ff-7967f96b8645.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-3G-AB0T-11A (Solid Tissue Normal), aliquot TCGA-3G-AB0T-11A-11D-A426-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a6c8c943-5797-4815-bc6d-b66c82539161

The open-access MAF lists 10 somatic variants for this specimen: 5 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 4, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RBM19 | c.2266G>A p.V756M | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs1322423676; called by muse, mutect2
- SLA | c.316G>A p.G106S (on ENST00000338087 / NM_001045556.3; = p.G146S on NM_006748.4) | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV55095302, COSV99599429; called by muse, mutect2
- TNFAIP8L1 | c.271C>T p.R91C | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV100542357; called by muse, mutect2
- FMN2 | c.4087A>G p.K1363E | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2
- IRX4 | c.571A>T p.T191S | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DENND2A | c.759C>T p.G253= | Silent (SNP) | VAF 4/45 reads (9%) | called by muse, mutect2, varscan2
- KRBA1 | c.537C>T p.P179= | Silent (SNP) | VAF 6/90 reads (7%) | catalogued as rs1481046928; called by muse, mutect2
- STK10 | c.1185C>T p.V395= | Silent (SNP) | VAF 5/48 reads (10%) | catalogued as rs146899945, COSV51574890; called by mutect2, varscan2
- UTP11 | c.642T>G p.V214= | Silent (SNP) | VAF 6/56 reads (11%) | called by muse, mutect2, varscan2
- H2BC15 | chr6:27838340 G>A | 5'Flank (SNP) | VAF 4/19 reads (21%) | catalogued as rs760717593; called by mutect2, varscan2
